Somatic mutation profile of tumor specimen TCGA-G7-6795-01A (aliquot TCGA-G7-6795-01A-11D-1961-08) from TCGA case TCGA-G7-6795, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 56.1 years (20,478 days).
Specimen TCGA-G7-6795-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 06dccf7b-c92e-41f8-9c9b-4f554f3c82c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G7-6795-10A (Blood Derived Normal), aliquot TCGA-G7-6795-10A-01D-1962-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a30252d2-337d-4e51-8111-0c33f252fe7d

The open-access MAF lists 60 somatic variants for this specimen: 41 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 17, In Frame Del 5, Nonsense Mutation 3, Frame Shift Ins 3, Frame Shift Del 2, Intron 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM17 | c.1427A>C p.K476T | Missense Mutation (SNP) | VAF 68/146 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV60399320; called by muse, mutect2, varscan2
- ADD3 | c.32C>G p.T11S | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.576); catalogued as COSV53322875; called by muse, mutect2, varscan2
- AGBL5 | c.2282A>G p.E761G | Missense Mutation (SNP) | VAF 46/159 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV64079815; called by muse, mutect2, varscan2
- AKR1B15 | c.597G>T p.L199F | Missense Mutation (SNP) | VAF 87/237 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71152087; called by muse, mutect2, varscan2
- ATAD2B | c.1762G>T p.D588Y | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53200321; called by muse, mutect2, varscan2
- BPIFA2 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.395); catalogued as COSV53611336; called by muse, mutect2, varscan2
- CACNA1G | c.2905G>A p.A969T | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV61729688; called by muse, mutect2, varscan2
- CC2D1B | c.2540C>G p.T847S | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as COSV52560771; called by muse, mutect2, varscan2
- DPYD | c.1093A>T p.K365* | Nonsense Mutation (SNP) | VAF 47/127 reads (37%) | catalogued as COSV64600112; called by muse, mutect2, varscan2
- DYM | c.1715C>T p.S572L | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.22); catalogued as COSV53986344; called by muse, mutect2, varscan2
- GJC1 | c.562G>C p.E188Q | Missense Mutation (SNP) | VAF 118/323 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57911442; called by muse, mutect2, varscan2
- IGSF9B | c.3494G>T p.G1165V | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.182); catalogued as rs1420816001, COSV58068715; called by muse, mutect2, varscan2
- IGSF9B | c.2074G>A p.D692N | Missense Mutation (SNP) | VAF 48/155 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); catalogued as COSV58068732; called by muse, mutect2, varscan2
- LAP3 | c.598C>A p.R200S | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56900076, COSV56900147; called by muse, mutect2, varscan2
- MPRIP | c.286G>A p.G96S | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59049240; called by muse, mutect2, varscan2
- MYCN | c.139dup p.E47Gfs*8 | Frame Shift Ins (INS) | VAF 20/52 reads (38%) | catalogued as COSV55259096; called by mutect2, pindel, varscan2
- NDFIP1 | c.571C>G p.L191V | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.645); catalogued as COSV54075058; called by muse, mutect2, varscan2
- P2RY1 | c.395A>G p.H132R | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV59309632; called by muse, mutect2, varscan2
- PHF12 | c.562A>T p.I188F | Missense Mutation (SNP) | VAF 46/79 reads (58%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.474); catalogued as COSV52019718; called by muse, mutect2, varscan2
- RALGAPA2 | c.4913T>A p.L1638* | Nonsense Mutation (SNP) | VAF 10/21 reads (48%) | catalogued as COSV52500330; called by muse, mutect2, varscan2
- RHBG | c.226G>C p.G76R | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV54806090; called by muse, mutect2, varscan2
- SAMD14 | c.1238A>C p.E413A (on ENST00000330175 / NM_001257359.2; = p.E441A on NM_174920.4) | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV50303852; called by muse, mutect2, varscan2
- SEC16A | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.911); catalogued as COSV51529929; called by muse, mutect2, varscan2
- SLC25A42 | c.545G>T p.G182V | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59380524; called by muse, mutect2, varscan2
- SSBP4 | c.215G>A p.C72Y | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as rs1326156119, COSV54210775; called by muse, mutect2, varscan2
- SYNPR | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 86/219 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs752748848, COSV55726391; called by muse, mutect2, varscan2
- TMPRSS9 | c.843-1G>A p.X281_splice (on ENST00000648592; = p.X247_splice on NM_182973.2) | Splice Site (SNP) | VAF 6/52 reads (12%) | catalogued as COSV60228268; called by mutect2, varscan2
- TROAP | c.268A>C p.N90H | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV57744669; called by muse, mutect2, varscan2
- UBR1 | c.3310G>A p.E1104K | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51930826; called by muse, mutect2, varscan2
- UGT1A5 | c.640A>G p.M214V | Missense Mutation (SNP) | VAF 184/338 reads (54%) | SIFT tolerated (0.51); PolyPhen benign (0.044); catalogued as COSV59390449; called by muse, mutect2, varscan2
- VEZF1 | c.323C>A p.T108N | Missense Mutation (SNP) | VAF 57/136 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs1360043986, COSV51968647; called by muse, mutect2, varscan2
- ZFHX3 | c.1398_1424del p.A472_E480del | In Frame Del (DEL) | VAF 15/49 reads (31%) | catalogued as rs765283007; called by muse*, mutect2, pindel*
- ZNF254 | c.1435A>T p.R479* | Nonsense Mutation (SNP) | VAF 17/65 reads (26%) | catalogued as COSV61642967; called by muse, mutect2, varscan2
- FARS2 | c.550_597del p.D184_L199del | In Frame Del (DEL) | VAF 7/85 reads (8%) | called by mutect2, pindel
- ITSN2 | c.1789_1791del p.E597del | In Frame Del (DEL) | VAF 21/108 reads (19%) | called by mutect2, pindel, varscan2
- LRRFIP1 | c.1821del p.E608Kfs*4 (on ENST00000392000 / NM_001137552.2; = p.E584Kfs*4 on NM_004735.4) | Frame Shift Del (DEL) | VAF 8/39 reads (21%) | called by mutect2, varscan2
- NDUFS1 | c.1203_1205del p.L402del | In Frame Del (DEL) | VAF 18/112 reads (16%) | called by pindel, varscan2
- TOPBP1 | c.4126_4127insAG p.R1376Kfs*67 | Frame Shift Ins (INS) | VAF 72/228 reads (32%) | called by mutect2, pindel, varscan2
- TPD52 | c.417_419del p.S140del (on ENST00000379097 / NM_001025252.3; = p.S100del on NM_005079.4 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 22/66 reads (33%) | called by mutect2, pindel, varscan2
- UBR3 | c.3762dup p.V1255Cfs*14 | Frame Shift Ins (INS) | VAF 26/123 reads (21%) | called by mutect2, pindel, varscan2
- USHBP1 | c.1033del p.A345Pfs*31 | Frame Shift Del (DEL) | VAF 11/37 reads (30%) | called by mutect2, pindel, varscan2
- ABCA13 | c.12831C>T p.N4277= | Silent (SNP) | VAF 75/215 reads (35%) | catalogued as COSV68947573; called by muse, mutect2, varscan2
- APOB | c.519C>T p.A173= | Silent (SNP) | VAF 89/153 reads (58%) | catalogued as COSV51938681; called by muse, mutect2, varscan2
- DDX60L | c.3645G>A p.R1215= | Silent (SNP) | VAF 58/118 reads (49%) | catalogued as COSV52714813; called by muse, varscan2
- IRAG1 | c.1215G>C p.R405= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs749691599, COSV70211403, COSV70211749; called by muse, mutect2, varscan2
- LAP3 | c.597A>G p.A199= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as COSV56900135; called by muse, mutect2, varscan2
- MBD6 | c.138C>A p.S46= | Silent (SNP) | VAF 39/119 reads (33%) | catalogued as COSV60765806; called by muse, mutect2, varscan2
- NDFIP1 | c.570C>A p.L190= | Silent (SNP) | VAF 43/173 reads (25%) | catalogued as COSV54075050; called by muse, mutect2, varscan2
- NPAT | c.3789T>C p.S1263= | Silent (SNP) | VAF 50/124 reads (40%) | catalogued as COSV53718594; called by muse, mutect2, varscan2
- OXR1 | c.1183T>C p.L395= (on ENST00000442977 / NM_001198532.1; = p.L394= on NM_018002.3) | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV56330379; called by muse, mutect2, varscan2
- RDH5 | c.798A>T p.R266= | Silent (SNP) | VAF 34/124 reads (27%) | catalogued as COSV57676524; called by muse, mutect2, varscan2
- SH3TC1 | c.2686C>T p.L896= | Silent (SNP) | VAF 56/108 reads (52%) | catalogued as COSV55285257; called by muse, mutect2, varscan2
- SLC13A1 | c.1227T>C p.P409= | Silent (SNP) | VAF 133/345 reads (39%) | catalogued as COSV52012675, COSV52013817; called by muse, mutect2, varscan2
- SPG11 | c.579T>A p.L193= | Silent (SNP) | VAF 52/141 reads (37%) | catalogued as COSV55996152; called by muse, mutect2, varscan2
- SPINT2 | c.144G>T p.R48= | Silent (SNP) | VAF 51/181 reads (28%) | catalogued as rs1421428605, COSV56648049; called by muse, mutect2, varscan2
- WDR70 | c.114C>T p.D38= | Silent (SNP) | VAF 65/203 reads (32%) | catalogued as COSV54274265; called by muse, mutect2, varscan2
- YY1AP1 | c.1482C>T p.L494= (on ENST00000295566 / NM_139118.2; = p.L437= on NM_018253.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/126 reads (30%) | catalogued as COSV55121853; called by muse, mutect2, varscan2
- ZNF471 | c.1596A>G p.Q532= | Silent (SNP) | VAF 35/107 reads (33%) | catalogued as COSV57291680; called by muse, mutect2, varscan2
- MIR668 | n.66C>G | RNA (SNP) | VAF 21/76 reads (28%) | catalogued as rs768823311; called by muse, mutect2, varscan2
- NACA | c.70+4031C>T | Intron (SNP) | VAF 25/43 reads (58%) | catalogued as COSV100771462, COSV63269775; called by muse, mutect2, varscan2
